Somatic mutation profile of tumor specimen TCGA-DB-A64R-01A (aliquot TCGA-DB-A64R-01A-11D-A29Q-08) from TCGA case TCGA-DB-A64R, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 24.5 years (8,947 days).
Specimen TCGA-DB-A64R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cc6919da-4989-4b8c-afcf-8feec091cc31.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DB-A64R-10A (Blood Derived Normal), aliquot TCGA-DB-A64R-10A-01D-A29Q-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cfc36a2e-c43f-4f44-a64a-d810b2092ebc

The open-access MAF lists 12 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 9, Nonsense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIC | c.4543C>T p.R1515C | Missense Mutation (SNP) | VAF 42/50 reads (84%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV50560816, COSV50584645; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 19/47 reads (40%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- C5orf34 | c.704A>G p.Y235C | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60930974; called by muse, mutect2, varscan2
- FARS2 | c.1243C>T p.R415C | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs759833179, COSV51170642; called by muse, mutect2, varscan2
- KDM4C | c.183T>G p.Y61* | Nonsense Mutation (SNP) | VAF 33/69 reads (48%) | catalogued as COSV67188551; called by muse, mutect2, varscan2
- LCN1 | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs199573452, COSV55018342; called by muse, mutect2, varscan2
- NBAS | c.2513C>T p.T838M | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as rs144830164; called by muse, mutect2, varscan2
- RENBP | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs782220053, COSV60074580; called by muse, mutect2, varscan2
- SLC35A2 | c.293T>A p.V98D | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.588); catalogued as COSV54431056, COSV54432013; called by muse, mutect2, varscan2
- SLC7A13 | c.1114A>C p.I372L | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV52535618; called by muse, mutect2, varscan2
- CDH16 | c.1896C>A p.Y632* | Nonsense Mutation (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- CSMD3 | c.6192T>C p.I2064= (on ENST00000297405 / NM_001363185.1; = p.I1960= on NM_052900.3) | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV52234093; called by muse, mutect2, varscan2
